Somatic mutation profile of tumor specimen TCGA-2J-AABH-01A (aliquot TCGA-2J-AABH-01A-21D-A40W-08) from TCGA case TCGA-2J-AABH, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 61.4 years (22,425 days).
Specimen TCGA-2J-AABH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59125f3e-0a2c-4d62-91b4-2dcb30b7d660.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABH-10A (Blood Derived Normal), aliquot TCGA-2J-AABH-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fab433e-d6f3-4c5d-9035-41b859772161

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/148 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 28/150 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.8026C>T p.R2676W | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs193922826, CM044255, COSV100616767; ClinVar: pathogenic / uncertain significance / risk factor; called by muse, mutect2, varscan2
- ABCB1 | c.3289G>T p.D1097Y | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99714111; called by muse, mutect2, varscan2
- ADAM17 | c.758A>T p.E253V | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100176485; called by muse, mutect2, varscan2
- ANGPTL2 | c.1359C>A p.Y453* | Nonsense Mutation (SNP) | VAF 133/580 reads (23%) | catalogued as COSV99402434; called by muse, mutect2, varscan2
- ARHGAP36 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1200019083, COSV52267262; called by muse, mutect2, varscan2
- B3GAT3 | c.49A>T p.I17F | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99642178; called by muse, mutect2, varscan2
- C1S | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196762; called by muse, mutect2, varscan2
- CCAR1 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV99771345; called by muse, mutect2, varscan2
- CDKN2A | c.47_50del p.L16Pfs*9 | Frame Shift Del (DEL) | VAF 31/106 reads (29%) | catalogued as rs587782206; called by pindel, varscan2
- CMYA5 | c.7121C>A p.S2374* | Nonsense Mutation (SNP) | VAF 40/211 reads (19%) | catalogued as COSV101484304; called by muse, mutect2, varscan2
- ENC1 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100188219; called by muse, mutect2, varscan2
- FUZ | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1428601860, COSV100571242; called by muse, mutect2, varscan2
- GRIN3B | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765385702, COSV99312835; called by muse, mutect2, varscan2
- IRS1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 85/483 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs949863472; called by muse, mutect2, varscan2
- KRTAP9-3 | c.334T>G p.C112G | Missense Mutation (SNP) | VAF 97/394 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV101370185; called by muse, mutect2, varscan2
- MAN2B2 | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV99577957; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 117/495 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99169627; called by muse, mutect2, varscan2
- MTMR12 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV53785198, COSV99373986; called by muse, mutect2, varscan2
- MYH7 | c.2809A>G p.T937A | Missense Mutation (SNP) | VAF 111/518 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100806523; called by muse, mutect2, varscan2
- NAA25 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99927960; called by muse, mutect2
- NOS1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs764344401, COSV100500499, COSV57611683, COSV57620123; called by muse, mutect2, varscan2
- OR14K1 | c.299T>C p.F100S | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99315425; called by muse, mutect2, varscan2
- OR4E2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs772069505, COSV57732499; called by muse, mutect2, varscan2
- PCDHA7 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 181/810 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782011323, COSV65348019; called by muse, mutect2, varscan2
- POLR2G | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.538); catalogued as COSV99585421; called by muse, mutect2, varscan2
- PRPS1L1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 99/454 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs376402121; called by muse, mutect2, varscan2
- PRSS23 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 108/483 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99722392, COSV99722558; called by muse, mutect2, varscan2
- RYR2 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 17/577 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV63670431; called by muse, mutect2
- SCN1A | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs1437209028, COSV57688842; called by muse, mutect2, varscan2
- SORCS2 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs377584831; called by muse, mutect2, varscan2
- SP100 | c.2563dup p.S855Kfs*11 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | catalogued as rs1479231987; called by mutect2, pindel, varscan2
- TP53 | c.184del p.E62Kfs*61 | Frame Shift Del (DEL) | VAF 225/852 reads (26%) | catalogued as CM120852, COSV52811974, COSV52991347; called by mutect2, pindel, varscan2
- TREX2 | c.311C>T p.T104M (on ENST00000334497; = p.T61M on NM_080701.3) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782164820, COSV57851036; called by muse, mutect2, varscan2
- KCNB2 | c.435dup p.E146Rfs*23 | Frame Shift Ins (INS) | VAF 136/352 reads (39%) | called by mutect2, varscan2
- PPP1R1B | c.96_111del p.R32Sfs*43 | Frame Shift Del (DEL) | VAF 42/267 reads (16%) | called by mutect2, pindel, varscan2
- AGER | c.144G>A p.R48= | Silent (SNP) | VAF 50/314 reads (16%) | catalogued as rs1380898303, COSV100905012; called by muse, mutect2, varscan2
- ANK3 | c.3876A>G p.L1292= (on ENST00000280772 / NM_001320874.2; = p.L426= on NM_001149.3) | Silent (SNP) | VAF 72/295 reads (24%) | catalogued as COSV99781930; called by muse, mutect2, varscan2
- ARC | c.1008C>T p.F336= | Silent (SNP) | VAF 82/469 reads (17%) | catalogued as rs367748647; called by muse, varscan2
- BCL11A | c.1320C>T p.N440= (on ENST00000335712 / NM_001365609.1; = p.N474= on NM_018014.4) | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV59624915, COSV59635637; called by muse, mutect2, varscan2
- CBARP | c.66C>T p.D22= (on ENST00000382477; = p.D28= on NM_152769.3) | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as rs146688767; called by muse, mutect2, varscan2
- IFNLR1 | c.342C>T p.S114= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs757282675, COSV100552288; called by muse, mutect2, varscan2
- LRP2 | c.7515C>T p.R2505= | Silent (SNP) | VAF 111/501 reads (22%) | catalogued as rs773316402, COSV55564114; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1983G>A p.V661= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV56624652; called by muse, mutect2, varscan2
- SYT16 | c.1242C>T p.F414= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV101413677; called by muse, mutect2, varscan2
- TUBA4A | c.1173G>A p.L391= | Silent (SNP) | VAF 75/380 reads (20%) | catalogued as COSV99944953; called by muse, mutect2, varscan2
- VEPH1 | c.2445C>T p.N815= | Silent (SNP) | VAF 81/326 reads (25%) | catalogued as rs995258016, COSV100747951, COSV62877958; called by muse, mutect2, varscan2
- ZWILCH | c.1587G>A p.Q529= | Silent (SNP) | VAF 67/192 reads (35%) | catalogued as COSV100328909; called by muse, mutect2, varscan2
- PLEC | chr8:143953742 C>T | 5'Flank (SNP) | VAF 31/273 reads (11%) | catalogued as COSV100518203; called by muse, mutect2, varscan2
